Somatic mutation profile of tumor specimen TCGA-06-0189-01A (aliquot TCGA-06-0189-01A-01D-1491-08) from TCGA case TCGA-06-0189, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.6 years (20,297 days).
Specimen TCGA-06-0189-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d45c1673-81bf-44d3-abfa-d4b74c407a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0189-10A (Blood Derived Normal), aliquot TCGA-06-0189-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f14d1676-cfce-4c9f-ac3d-c2f9ee305777

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 12/156 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- AASS | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746536178, COSV62789589; called by muse, mutect2
- ABCC9 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53975306; called by muse, mutect2, varscan2
- CACNA1H | c.2932G>A p.V978M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs771078778, COSV61993677; called by mutect2, varscan2
- GRM8 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769982247, COSV58835217; called by muse, mutect2
- HMCN1 | c.286A>T p.I96F | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV54909136; called by muse, mutect2, varscan2
- KRT12 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770184655, COSV52429589; called by muse, mutect2
- NCKAP5 | c.2571T>G p.F857L | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV58450915; called by muse, mutect2
- NPBWR2 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63899758; called by muse, mutect2
- OR5D13 | c.278C>A p.T93N | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV62334129, COSV62335766; called by muse, mutect2
- PLA2G4E | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs759986725, COSV68150401; called by muse, mutect2, varscan2
- SRSF2 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV57971537, COSV57973286; called by muse, mutect2
- TM4SF19 | c.418T>C p.Y140H | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV56556885; called by muse, mutect2
- UXS1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV51678559; called by muse, mutect2, varscan2
- METTL27 | c.717G>A p.R239= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1399507823, COSV52896208; called by muse, mutect2, varscan2
- MFSD5 | c.1122G>A p.Q374= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV61565711; called by muse, mutect2
